Surgical pathology report (de-identified scan), TCGA case TCGA-B8-A54H, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma), tissue source site UNC, specimen TCGA-B8-A54H-01A (Primary Tumor).

[page 1 of 4]
ICD6-3

Carcinoma, renal cell NOS

Clear Cell type

831213

Site: (D) Kidney NOS
C64.9

11/30/12 Jw

Diagnosis:

A: Kidney, left, laparoscopic radical nephrectomy

Tumor #1

Histologic tumor type/subtype: renal cell carcinoma,
conventional clear cell type

Sarcomatoid features: not identified

Histologic grade (if applicable): Fuhrman nuclear grade 3 (of 4)

Tumor size (greatest dimension): 7.5 cm

Tumor focality: unifocal, mid and superior pole

Extent of tumor invasion (if present specify if macroscopic or
microscopic):

Capsular invasion/perirenal adipose tissue: not identified

Gerota's fascia: not identified

Renal sinus: not identified

Major veins (renal vein or segmental branches, IVC): not
identified

Ureter: not identified

Venous (large vessel): present, microscopic

Lymphatic (small vessel): not identified

Histologic assessment of surgical margins:

Gerota's fascia (nephrectomy): negative

Renal vein (nephrectomy): negative

Ureter (nephrectomy): negative

Adrenal gland: not submitted

Lymph nodes: no tumor seen in one lymph node (0/1)

Pathologic findings in non-neoplastic kidney:
arteriolonephrosclerosis

AJCC Staging: pT2a pN0

This staging information is based on information available at
the time of this report, and is subject to change pending
clinical review and additional information.

[page 2 of 4]
Tumor #2

Histologic tumor type/subtype: papillary renal cell carcinoma,
type 1

Sarcomatoid features: not identified

Histologic grade (if applicable): Fuhrman nuclear grade 2 (of 4)

Tumor size (greatest dimension): 0.8 cm

Tumor focality: unifocal

Extent of tumor invasion (if present specify if macroscopic or
microscopic):

Capsular invasion/perirenal adipose tissue: not identified

Gerota' s fascia: not identified

Renal sinus: not identified

Major veins (renal vein or segmental branches, IVC): not
identified

Ureter: not identified

Venous (large vessel): not identified

Lymphatic (small vessel): not identified

Histologic assessment of surgical margins:

Gerota' s fascia (nephrectomy): negative

Renal vein (nephrectomy): negative

Ureter (nephrectomy): negative

Adrenal gland: not submitted

Lymph nodes: no tumor seen in one lymph node (0/1)

Pathologic findings in non-neoplastic kidney:
arteriolonephrosclerosis

AJCC Staging pT1a pN0

This staging information is based on information available at
the time of this
report, and is subject to change pending clinical review and
additional
information.

[page 3 of 4]
Clinical History:

The patient is a year-old female with left renal mass. Radiology reveals a 10.7 x 5.8 cm exophytic mass arising from the upper pole of the left kidney concerning for extension into the perinephric space to Gerota' s fascia by imaging.

Gross Description:

Received is one appropriately labeled container, additionally labeled "left kidney."

Specimen fixation: fresh, and later placed in formalin

Type of specimen: laparoscopic left radical nephrectomy

Side of specimen: per requisition, left

Size and weight of specimen: 20.6 x 12.4 x 5.8 cm, 515 grams with the majority of the fat removed

Orientation: The Gerota' s fascia fat remaining on the specimen is inked blue.

Presence/absence of adrenal gland: absent

Tumor site: mid and superior pole, grossly appearing to arise from the cortex

Tumor description: The tumor is somewhat circumscribed, tan/yellow to red, variegated with white fibrous areas throughout

Tumor size: roughly 7.5 x 6.0 x 4.5 cm

Presence/absence of multicentricity: absent

Confinement/non-confinement to the kidney: confined

Extent of invasion:

Perirenal adipose tissue: does not involve

Gerota' s fascia: does not involve

Renal vein: does not involve

[page 4 of 4]
Ureter: does not involve

Renal Sinus: does not involve

Pelvicocaliceal: does not involve

Adrenal: not present

Other organs: n/a

Surgical margins:

Perirenal adipose tissue: negative

Renal vein: negative

Renal artery: negative

Ureter: negative

Description of kidney away from tumor: kidney parenchyma away from mass is red/brown with a distinct corticomedullary junction

Hilar lymph nodes: none identified

Other significant findings: none

Tissue submitted for special investigations: yes; Tumor and normal are submitted to Tissue Procurement.

Digital picture: no

Block summary:

A1 - vascular and ureteral margin taken at the time of triage
A2,A3 - mass with respect to blue inked Gerota' s fascia, perpendicular
A4,A5 - additional section of mass, different appearing areas with adjacent normal kidney
A6 - mass and sinus fat and adjacent normal kidney
A7 - additional section of mass, grossly different areas
A8 - representative section of normal kidney away from mass

	Yes	No
Critique		
HPA's Discrepancy		
Qual/Synch/Primary/Other		
Case by (initials)		
Reviewed by (initials)		

W-24312
KMI
11/26/12

Source: NCI Genomic Data Commons file 3225bf27-e5b8-467a-97d6-505ee9250919 (TCGA-B8-A54H.07ACF9DE-5569-49FD-9083-383C7A12DE33.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).